Surgical pathology report (de-identified scan), TCGA case TCGA-W5-AA2Z, project TCGA-CHOL (Cholangiocarcinoma), tissue source site Mayo Clinic Rochester, specimen TCGA-W5-AA2Z-01A (Primary Tumor).

Female
Surgery Date:

DIAGNOSIS:

A. Gallbladder, cholecystectomy: Chronic cholecystitis with cholesterosis. One cystic duct lymph node is negative for tumor.

B. Lymph node, pericholedochal, excision: One lymph node is negative for tumor.

C. Liver, right, partial hepatectomy: Grade 3 (of 4) cholangiocarcinoma, is identified forming a solid mass (20.0 x 13.5 x 11.2 cm) and a separate nodule (2.2 x 1.8 x 1.4 cm). The tumor is confined to hepatic parenchyma. The tumor growth pattern is mass-forming. The tumor extends to the hepatic parenchymal resection margin. Major vessel invasion is absent. Microscopic invasion is absent. No regional lymph nodes identified. The background liver parenchyma will be reported in an addendum

D. Liver, segment II nodule, wedge biopsy: Bile duct hamartoma.

ICD-03
Cholangiocarcinoma 8160/3
Site Intrahepatic bile duct 0221
JW 8/18/14

Source: NCI Genomic Data Commons file 6b27d22c-bbb6-462b-ae5b-18f6370f8799 (TCGA-W5-AA2Z.22F994D3-20A5-46CD-958F-2AAAB3F2D2EC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).